Somatic mutation profile of tumor specimen 0DGSRA from CCDI case PBBTWG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.8 years (1,753 days).
Specimen 0DGSRA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 127a358a-b0df-4834-93fc-a3f7901969b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGSR6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b974b02e-16d3-4f5f-8373-4baacb1b8ec1

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, RNA 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.3487C>T p.R1163* | Nonsense Mutation (SNP) | VAF 168/336 reads (50%) | catalogued as COSV60713352; called by muse, varscan2
- GCNT1 | c.868G>A p.V290M | Missense Mutation (SNP) | VAF 429/822 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781163105; called by muse, varscan2
- OTUD6A | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 36/309 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57973757; called by muse, varscan2
- SLC6A6 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 267/620 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.489); catalogued as rs1479735023; called by muse, varscan2
- STAP2 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 156/388 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746019430, COSV74071001; called by muse, varscan2
- ACOT9 | c.933T>G p.F311L | Missense Mutation (SNP) | VAF 198/514 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ALDH2 | c.336C>T p.I112= | Silent (SNP) | VAF 159/619 reads (26%) | catalogued as rs199967065; called by muse, varscan2
- KMT2B | c.4104C>T p.C1368= | Silent (SNP) | VAF 82/463 reads (18%) | catalogued as rs751697082; called by muse, varscan2
- TENM1 | c.8079C>T p.Y2693= | Silent (SNP) | VAF 338/797 reads (42%) | catalogued as rs922656785; called by muse, varscan2
- C8orf87 | n.180C>T | RNA (SNP) | VAF 427/996 reads (43%) | catalogued as rs910481074; called by muse, varscan2
- WDR13 | c.283-33A>G | Intron (SNP) | VAF 116/303 reads (38%) | called by muse, varscan2
